TCGA case TCGA-AP-A0LF — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/748e38b1-2ead-4a0a-8881-d640617b856b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (2)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2002; Method of diagnosis: Biopsy; FIGO stage: Stage IVB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 2,845 days (7.8 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 10.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 14; Lymph nodes tested: 32.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 17.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Intraductal carcinoma, noninfiltrating, NOS: ICD-O-3 morphology code: 8500/2; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 2,845 days (7.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 161 cm; BMI: 27.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AP-A0LF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-AP-A0LF-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AP-A0LF-01A-01-BSA: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AP-A0LF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AP-A0LF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form 1: Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: Yes.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Ductal carcinoma in situ.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,859 days; disease-specific survival: no event (censored), 2,859 days; progression-free interval: no event (censored), 2,859 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AP-A0LF-01A-11D-A120-01): tumor purity 0.38, ploidy 3.24, whole-genome doublings 1.
